Somatic mutation profile of tumor specimen MMRF_2153_1_BM_CD138pos (aliquot MMRF_2153_1_BM_CD138pos_T1_KHS5U_L08673) from MMRF case MMRF_2153, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.0 years (28,845 days).
Specimen MMRF_2153_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25934974-9535-40c1-a761-93b052bffd03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2153_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2153_1_PB_Whole_C2_KHS5U_L08674; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1577d488-a509-4219-b339-48aeffff8e74

The open-access MAF lists 55 somatic variants for this specimen: 23 protein-altering or splice-affecting, 11 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, 3'UTR 11, Silent 11, 3'Flank 3, 5'Flank 3, Nonsense Mutation 2, 5'UTR 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOP1B | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs1357546985, COSV67693742; called by muse, mutect2
- HOXC10 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773443415; called by muse, mutect2
- IGHV3-53 | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.342); catalogued as rs781882434; called by muse, varscan2
- IGLV2-11 | c.154A>G p.N52D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.019); catalogued as rs560424379; called by muse, varscan2
- NFX1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.978); catalogued as COSV59313557; called by muse, mutect2
- NKIRAS2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs781985896, COSV56918097; called by muse, mutect2
- SOGA1 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs897979650; called by muse, mutect2
- ZCCHC14 | c.509G>A p.R170Q (on ENST00000268616; = p.R307Q on NM_015144.3) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1255394794, COSV99233349; called by muse, mutect2
- ABCG8 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AL592490.1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2
- ARID1B | c.836G>A p.S279N | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- ATP1A1 | c.478T>C p.S160P | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CER1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.751); called by muse, mutect2
- KDM4B | c.1935T>A p.D645E | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.452); called by muse, mutect2
- MAP4K1 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- METTL27 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- MMEL1 | c.669G>A p.M223I | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2
- MPPED2 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.063); called by muse, mutect2
- NRG3 | c.1957A>G p.I653V (on ENST00000404547 / NM_001370084.1; = p.I629V on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.522); called by muse, mutect2
- NUP155 | c.2257A>C p.N753H (on ENST00000231498 / NM_153485.3; = p.N694H on NM_004298.4) | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); called by muse, mutect2
- PEX5 | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PPP3CB | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.254); called by mutect2, varscan2
- TOP2B | c.1463C>T p.S488L (on ENST00000264331 / NM_001330700.2; = p.S483L on NM_001068.3) | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2
- ADD1 | c.663C>T p.F221= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV53267129; called by muse, mutect2
- DECR1 | c.31C>T p.L11= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as rs1187455871, COSV55168572; called by muse, mutect2
- EFNB1 | c.672G>T p.G224= | Silent (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- FLNC | c.1257C>T p.G419= | Silent (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- FRMD7 | c.1785C>T p.D595= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- IGHV1-69 | c.150C>T p.S50= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs11546800; called by mutect2, varscan2
- IGHV2-70 | c.12T>G p.L4= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs373050389; called by mutect2, varscan2
- PCDHB1 | c.1548G>A p.A516= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as rs1185017215, COSV60629767; called by muse, mutect2
- RIMS1 | c.285G>A p.V95= | Silent (SNP) | VAF 6/123 reads (5%) | called by muse, mutect2
- TOPORS | c.162G>A p.A54= | Silent (SNP) | VAF 10/196 reads (5%) | catalogued as COSV100598260; called by muse, mutect2
- TRAV21 | c.199T>C p.L67= | Silent (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- AC040977.2 | chr17:6985269 G>C | 3'Flank (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- BDKRB2 | c.*277C>A | 3'UTR (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- CHFR | chr12:132836877 C>T | 3'Flank (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- ENKUR | c.*582A>T | 3'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- GTF2A1 | c.*2069C>T | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- HCAR3 | c.*471G>A | 3'UTR (SNP) | VAF 19/557 reads (3%) | called by muse, mutect2
- KLHL14 | chr18:32773338 G>A | 5'Flank (SNP) | VAF 7/151 reads (5%) | called by muse, mutect2
- MIR5195 | chr14:106851342 C>T | 5'Flank (SNP) | VAF 15/123 reads (12%) | catalogued as rs544762978; called by muse, varscan2
- N4BP3 | c.*2871C>T | 3'UTR (SNP) | VAF 21/188 reads (11%) | catalogued as rs1314118090; called by muse, mutect2, varscan2
- OPRK1 | c.*3475A>C | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- PAPOLG | c.*385A>G | 3'UTR (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- PDCD6IPP1 | n.936G>A | RNA (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- PLD3 | chr19:40348542 G>C | 5'Flank (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- PTAFR | chr1:28148140 C>T | 3'Flank (SNP) | VAF 7/92 reads (8%) | catalogued as rs1330375330; called by muse, mutect2
- PTPRE | c.*1104C>T | 3'UTR (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- ROMO1 | c.-168C>A | 5'UTR (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- SLC26A7 | c.*837A>T | 3'UTR (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-437T>A | 5'UTR (SNP) | VAF 17/50 reads (34%) | called by mutect2, varscan2
- ST6GAL2 | c.*4464A>G | 3'UTR (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- TBC1D30 | c.*2896C>T | 3'UTR (SNP) | VAF 24/169 reads (14%) | called by muse, mutect2, varscan2
- VPS52 | c.1906+96G>A | Intron (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
